Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A0S7, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A0S7-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: URETERAL MARGIN, RIGHT, FROZEN SECTION -

- A. UROTHELIAL DYSPLASIA.
- B. NO EVIDENCE OF INVASIVE CARCINOMA.

PART 2: URETERAL MARGIN, LEFT, FROZEN SECTION -

- A. BENIGN.
- B. UROTHELIUM WITH REACTIVE CHANGES.

PART 3: URETERAL MARGIN, RIGHT, FROZEN SECTION -

- A. BENIGN UROTHELIUM.
- B. NO EVIDENCE OF MALIGNANCY.

PART 4: BLADDER AND PROSTATE, RADICAL CYSTOPROSTATECTOMY -

- A. INVASIVE UROTHELIAL CARCINOMA, HIGH-GRADE, WITH SQUAMOUS DIFFERENTIATION AND EXTENSIVE NECROSIS, INVOLVING THE BLADDER, PROSTATE AND LEFT SEMINAL VESICLES.
- B. THE TUMOR INVADES THE DETRUSOR MUSCLE AND EXTENDS INTO THE PERIVESICAL FAT
- C. THE TUMOR INVOLVES INKED PROSTATIC RESECTION MARGINS (SLIDES 40 AND 4N) AND THE DISTAL URETHRAL RESECTION MARGIN (SLIDE 4D).
- D. PERINEURAL INVASION IS IDENTIFIED.
- E. EXTENSIVE ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. TNM STAGE: pT4a N0 Mx.
- G. HISTOLOGIC GRADE: G3.

PART 5: LYMPH NODES, LEFT PELVIC, DISSECTION -

NO EVIDENCE OF MALIGNANCY IN 14 (FOURTEEN) LYMPH NODES EXAMINED (0/14).

PART 6: LYMPH NODES, RIGHT PELVIC, DISSECTION -

NO EVIDENCE OF MALIGNANCY IN 10 (TEN) LYMPH NODES EXAMINED (0/14).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Trigone, Right lateral wall, Left lateral wall, Anterior wall, Posterior wall, Dome
TUMOR SIZE: Cannot be determined (see Comment)
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma with squamous differentiation
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Papillary, Solid/nodule
PATHOLOGIC STAGING (pTNM): pT4a
pN0
Number of nodes examined: 24
Number of nodes involved: 0
pMX
MARGINS: Margin(s) involved by invasive carcinoma
Margin(s): urethral resection margin; prostate
VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Present

DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat
Prostatic stroma

ADDITIONAL PATHOLOGIC FINDINGS: Urothelial dysplasia (low-grade intraurothelial neoplasia)

1C8-0-3

carcinoma, urothelial, NOS 8/20/3

Site: bladder, NOS 6/7/4

hw
11/22/11

Source: NCI Genomic Data Commons file d2ec8962-e1ef-4e57-82e3-6a2bcf68dc51 (TCGA-BT-A0S7.FF162E4D-8399-4DD8-BCD6-7D4D701CD7E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).